CTSP case CTSP-AD4K — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4a69b6e0-390c-46ca-a3df-c34c536cc109

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1933; Vital status: Dead; Days to death: 1,095 days (3.0 years); Year of death: 2009; Cause of death: Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 73.2 years (26,750 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage III; Days to last follow up: 1,095 days (3.0 years); Best overall response: Complete Response; Ann Arbor extranodal involvement: No; Double expressor lymphoma: No; Double hit lymphoma: No; International Prognostic Index (IPI): High-Intermediate Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85 kg; Height: 180 cm; BMI: 26.2.

Biospecimens (1 sample)
- Sample DLBCL11279-sample: Sample type: Tumor; Tissue type: Tumor.
